Somatic mutation profile of tumor specimen TCGA-Q9-A6FW-01A (aliquot TCGA-Q9-A6FW-01A-31D-A31U-09) from TCGA case TCGA-Q9-A6FW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.8 years (22,586 days).
Specimen TCGA-Q9-A6FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c1d29d0-32b6-4a72-810e-6b1cc45c1f0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q9-A6FW-10A (Blood Derived Normal), aliquot TCGA-Q9-A6FW-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7556e38c-0e62-4e60-b3c0-374344137dc1

The open-access MAF lists 198 somatic variants for this specimen: 153 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 40, Nonsense Mutation 9, In Frame Del 4, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, Splice Site 2, Intron 1, In Frame Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1528G>T p.G510* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | hotspot (GDC flag); catalogued as COSV61688753, COSV61690376; called by muse, mutect2, varscan2
- ACTL9 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs781910740, COSV61006476; called by muse, mutect2, varscan2
- ADAM18 | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1404718839, COSV55846015, COSV55846388; called by muse, mutect2, varscan2
- ADAMTS20 | c.4886T>G p.L1629R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV67129048; called by muse, mutect2, varscan2
- ADAMTS7 | c.3377G>T p.G1126V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs779430929; called by muse, mutect2
- AGBL1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs763367858; called by mutect2, varscan2
- ANKRD35 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1553738943, COSV62911223; called by muse, mutect2
- ATM | c.4673C>T p.T1558M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs587781712, COSV53767118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARHL1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55037821; called by muse, varscan2
- BCAN | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372404921; called by muse, mutect2, varscan2
- CCNJ | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.4); catalogued as rs201944303; called by muse, mutect2
- CD244 | c.488G>A p.G163D (on ENST00000368033 / NM_001166663.2; = p.G158D on NM_016382.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs771548413; called by muse, mutect2, varscan2
- CENPF | c.8146G>A p.D2716N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV65279558; called by muse, mutect2
- CHRNB1 | c.1418G>A p.W473* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs772731018; called by muse, mutect2, varscan2
- CLIP4 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.175); catalogued as rs1171501228, COSV100192257; called by muse, mutect2, varscan2
- DNAH1 | c.8351C>T p.S2784L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs1401694763, COSV70231267; called by mutect2, varscan2
- EIF5B | c.2551G>C p.A851P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV56811792; called by muse, mutect2, varscan2
- EPPK1 | c.5620C>T p.R1874C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs372213876; called by muse, mutect2, varscan2
- ETV3L | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs202076672; called by muse, mutect2
- FAM160A2 | c.1645G>A p.D549N (on ENST00000449352 / NM_001098794.2; = p.D563N on NM_032127.4) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.077); catalogued as rs773004260; called by muse, mutect2, varscan2
- FAT3 | c.6190C>T p.R2064C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759701930, COSV53099657; called by muse, mutect2, varscan2
- FBN1 | c.8005G>A p.G2669S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as rs794728281, CM154865; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FLNA | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs1557177704, COSV61037792; called by muse, mutect2, varscan2
- HSF4 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as rs761168989; called by muse, mutect2, varscan2
- KCTD19 | c.1940G>A p.C647Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs200456334; called by muse, mutect2, varscan2
- KIF1A | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs751960710, COSV57494413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCE3A | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100175092, COSV59551214; called by muse, mutect2, varscan2
- LPA | c.4313G>T p.R1438M | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60314814; called by muse, mutect2, varscan2
- MRPL40 | c.163_165del p.K55del | In Frame Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs778257898; called by pindel, varscan2
- MUC17 | c.10351T>G p.S3451A | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.925); catalogued as COSV60297620; called by muse, mutect2, varscan2
- MUC4 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.494); catalogued as rs746086662; called by muse, mutect2
- MUC6 | c.6077_6079del p.I2026del | In Frame Del (DEL) | VAF 55/420 reads (13%) | catalogued as rs775399282; called by pindel, varscan2
- NAA16 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs1428409589, COSV65065536; called by muse, mutect2, varscan2
- NAGLU | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as CD982816; called by muse, mutect2, varscan2
- NDEL1 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs751878083; called by muse, mutect2, varscan2
- NME9 | c.169G>A p.G57S (on ENST00000333911 / NM_001349024.2; = p.G35S on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as rs767013134; called by muse, mutect2, varscan2
- NUCB1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375589971; called by muse, mutect2, varscan2
- OR4A5 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs567373135; called by muse, mutect2
- OR5M1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV101591621; called by muse, mutect2, varscan2
- PCNX3 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs763839897; called by muse, mutect2, varscan2
- PDE11A | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs560754146, COSV104376009; called by muse, mutect2, varscan2
- PDE1C | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1360269609, COSV58507262; called by muse, mutect2, varscan2
- PLA2G4D | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1466794070; called by muse, mutect2, varscan2
- POU4F3 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57942329; called by muse, mutect2, varscan2
- PPARG | c.1424C>T p.T475M (on ENST00000287820 / NM_015869.5; = p.T445M on NM_005037.7) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1479145908, COSV55141227; called by muse, mutect2, varscan2
- PTCD1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs375579760, COSV52856145; called by muse, mutect2, varscan2
- RAD17 | c.1609C>T p.R537W (on ENST00000380774 / NM_133339.2; = p.R526W on NM_002873.1) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as rs376862416; called by muse, mutect2, varscan2
- SCN3A | c.3449G>A p.R1150Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs775381308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC1 | c.3401T>C p.I1134T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV52463932; called by muse, mutect2
- SMARCB1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54093830; called by muse, mutect2, varscan2
- SPTA1 | c.4870T>C p.S1624P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV63760148; called by muse, mutect2, varscan2
- STAU2 | c.1012C>T p.R338* (on ENST00000524300 / NM_001164380.2; = p.R306* on NM_014393.2) | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs777515554; called by muse, mutect2, varscan2
- STOX1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1326177304; called by muse, mutect2, varscan2
- SYNE1 | c.10469T>C p.L3490P (on ENST00000367255 / NM_182961.4; = p.L3497P on NM_033071.3) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs765879613; called by muse, mutect2, varscan2
- SYNE3 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs142727232; called by mutect2, varscan2
- TCF20 | c.3970G>A p.D1324N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV59488542; called by muse, mutect2
- TPST2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV58678481; called by muse, mutect2, varscan2
- TRIM60 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as rs762704763; called by muse, mutect2, varscan2
- TTC21B | c.3023T>G p.F1008C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54627637; called by muse, mutect2, varscan2
- TTN | c.1107G>T p.Q369H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | PolyPhen benign (0.006); catalogued as COSV60017466; called by muse, mutect2, varscan2
- ULK4 | c.3008C>G p.P1003R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1252270191; called by mutect2, varscan2
- UNC13C | c.5024T>G p.L1675R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52863492; called by muse, mutect2, varscan2
- WDR3 | c.2571C>G p.F857L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1195124113; called by muse, mutect2
- ZBTB4 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210442686, COSV104410173; called by mutect2, varscan2
- ZDHHC8 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57711257; called by muse, mutect2
- ZNF44 | c.601C>T p.R201C (on ENST00000356109 / NM_001164276.2; = p.R153C on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs375321557; called by muse, mutect2
- ZNF521 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.407); catalogued as rs146072050; called by muse, mutect2, varscan2
- ZNF823 | c.1126C>T p.R376* (on ENST00000341191 / NM_001297610.2; = p.R332* on NM_017507.2) | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs773804721, COSV100362374; called by muse, mutect2, varscan2
- ADAMTS17 | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by mutect2, varscan2
- ADAMTS20 | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AKAP13 | c.4961A>T p.D1654V (on ENST00000394518 / NM_007200.5; = p.D1658V on NM_006738.6) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.121); called by muse, mutect2
- ANKRD7 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- APEX1 | c.493T>G p.F165V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- BARHL2 | c.718dup p.S240Ffs*11 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- CALR3 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL28 | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- CELA3A | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CLDN8 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.219); called by muse, mutect2
- CYP27C1 | c.881G>A p.W294* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- DAOA | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- DHTKD1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAJC25 | c.600dup p.A201Sfs*16 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- DOCK2 | c.174T>G p.I58M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2
- DPP10 | c.1727T>G p.V576G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC1LI2 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- EMILIN1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENTHD1 | c.1718T>G p.L573R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPB41L1 | c.1000T>G p.F334V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EQTN | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- F11 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM222A | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FANCD2 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- FGGY | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- GABRB1 | c.380A>C p.K127T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GALNT13 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GPR161 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.088); called by muse, mutect2
- H1-5 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- H3C4 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HDAC3 | c.135_137del p.M45del | In Frame Del (DEL) | VAF 22/156 reads (14%) | called by pindel, varscan2
- HERC2 | c.11226C>A p.N3742K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.019); called by muse, mutect2
- HIPK1 | c.3532_3533del p.Q1178Vfs*65 (on ENST00000369558 / NM_001369806.1; = p.Q784Vfs*65 on NM_181358.2) | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- ICAM3 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- IGSF11 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNH5 | c.572T>G p.I191S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.258); called by muse, mutect2
- KIR3DL1 | c.789A>C p.E263D | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KMT2D | c.10582C>A p.L3528I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LAMA1 | c.5178A>C p.E1726D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- MACF1 | c.3841C>G p.R1281G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- MAMDC2 | c.1918_1920del p.F640del | In Frame Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- MICAL2 | c.5688G>T p.E1896D | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MROH7 | c.2246G>A p.G749D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2
- MTTP | c.2342+3_2342+6del p.X781_splice | Splice Site (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- NIN | c.4379A>T p.K1460M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- NLK | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2
- ODR4 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- OR1J4 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR2G2 | c.853A>C p.T285P | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR5I1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- PATZ1 | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDH15 | c.1486A>G p.N496D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- PIK3R3 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PPP4R4 | c.1481C>G p.A494G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- PROX1 | c.935G>C p.R312P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- PTPRZ1 | c.6427A>G p.N2143D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RALGAPA1 | c.5184A>C p.Q1728H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RAP1GDS1 | c.1522A>G p.N508D | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- REV3L | c.7651T>G p.F2551V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGS12 | c.990_992dup p.G331dup | In Frame Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel
- RUNDC3B | c.611A>C p.K204T | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SAV1 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SAXO2 | c.867T>G p.F289L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SCAF4 | c.1819G>C p.V607L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.437); called by muse, mutect2
- SCN10A | c.125_127delinsA p.R42Kfs*27 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by pindel, varscan2*
- SLAMF8 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC17A6 | c.1355T>G p.V452G | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC22A11 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMCR8 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by mutect2, varscan2
- SNED1 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK39 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBPL2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM132D | c.739A>C p.S247R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.048); called by muse, mutect2
- TMPO | c.1212G>T p.K404N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2
- TNRC6C | c.2682G>C p.E894D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- TNXB | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TRAV1-1 | c.151T>C p.W51R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM31 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIM55 | c.938A>C p.N313T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TTN | c.32730G>C p.K10910N (on ENST00000591111; = p.K9983N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TXLNB | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB48 | c.2058_2059del p.C686* | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by pindel, varscan2
- ZNF280D | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ZNF536 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ZNF626 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- ADGRB3 | c.2397C>T p.T799= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs200795351; called by muse, varscan2
- ADRM1 | c.549G>A p.L183= | Silent (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- AFDN | c.4809G>A p.A1603= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs374331983; called by muse, mutect2, varscan2
- BCL9 | c.1515C>T p.H505= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs782720985, COSV52346478, COSV52347304; called by muse, mutect2, varscan2
- BTK | c.879A>G p.Q293= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.375C>T p.Y125= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- CAPRIN1 | c.591G>A p.R197= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- CCR1 | c.411C>T p.H137= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs768750994; called by muse, mutect2, varscan2
- CDH5 | c.489G>A p.S163= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs370305306; called by mutect2, varscan2
- CEACAM4 | c.576G>A p.P192= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs782062058; called by muse, mutect2, varscan2
- CSMD1 | c.5718G>T p.L1906= (on ENST00000520002; = p.L1905= on NM_033225.6) | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- DGUOK | c.99C>T p.H33= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- EMILIN1 | c.2829A>G p.V943= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- FBXO32 | c.726C>T p.D242= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs200895126; called by muse, mutect2, varscan2
- GP2 | c.1443A>G p.Q481= (on ENST00000381362 / NM_001007240.3; = p.Q478= on NM_001502.4) | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- GPM6A | c.384T>C p.A128= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- GPX5 | c.609G>A p.T203= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs567969552, COSV69079092, COSV69079406; called by muse, mutect2, varscan2
- GRIK3 | c.2142G>A p.K714= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- GTF2I | c.924A>G p.E308= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.1683T>C p.D561= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1234141921; called by muse, mutect2, varscan2
- KLHL6 | c.150C>T p.D50= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs201171041, COSV58066430; called by mutect2, varscan2
- LMF1 | c.1281C>T p.S427= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs1298053437; called by muse, mutect2, varscan2
- LMNB2 | c.1671C>T p.G557= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1268005932; called by muse, mutect2, varscan2
- MRPL30 | c.42C>A p.G14= | Silent (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- MYLK2 | c.1074C>T p.F358= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- PTPRJ | c.2235C>T p.G745= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs755561818; called by muse, mutect2, varscan2
- RELN | c.3198G>A p.P1066= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs767180170, COSV100634141; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF31 | c.1050A>C p.A350= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- SASH1 | c.228C>T p.D76= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs749204773, COSV66560639; called by muse, mutect2, varscan2
- SERTAD3 | c.504A>G p.P168= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3708C>T p.A1236= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs542753643; called by muse, mutect2, varscan2
- SLC26A1 | c.816G>A p.A272= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs139361937; called by muse, mutect2, varscan2
- ST3GAL2 | c.720C>T p.Y240= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs566916255; called by muse, mutect2
- STK3 | c.321C>A p.V107= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- STON1 | c.2202T>C p.T734= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- TRIM3 | c.924G>A p.S308= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1176284010, COSV61985856; called by muse, mutect2, varscan2
- UNC13C | c.5466T>G p.S1822= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1231802487; called by muse, mutect2, varscan2
- XKR7 | c.1401C>T p.D467= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1310101503, COSV73812896; called by mutect2, varscan2
- ZFP28 | c.2589C>G p.S863= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- ZNF439 | c.1036A>C p.R346= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- ARPP19P2 | n.218A>T | RNA (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- CAPN1 | chr11:65214058 C>T | 3'Flank (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2
- LCP1 | c.*1G>A | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.575C>G | RNA (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- RBM44 | c.-98-2482A>C | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
